CCDI case PBCMEU — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Other and ill-defined sites within respiratory system and intrathoracic organs.
https://portal.gdc.cancer.gov/cases/3990a310-bb0e-4252-90cc-06b606ca51a3

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Pleuropulmonary blastoma: ICD-O-3 morphology code: 8973/3; Tissue or organ of origin: Lung, NOS; Age at diagnosis: 2.7 years (990 days).

Biospecimens (3 samples)
- Sample 0DV4IR: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DV4J0: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DV4KV: Tissue type: Tumor; Specimen type: Solid Tissue.
